Gene-level copy-number profile of tumor specimen TCGA-AC-A3OD-01B from TCGA case TCGA-AC-A3OD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.0 years (25,186 days).
Specimen TCGA-AC-A3OD-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.339d0eca-df55-41e8-8415-9017c03018df.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A3OD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 364 have no estimate.
https://portal.gdc.cancer.gov/files/565affe7-21ea-4129-8dce-30d42af4a855

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 588; copy number 1: 11,538; copy number 2: 41,100; copy number 3: 3,830; copy number 4: 2,012; copy number 5: 1,037; copy number 6: 6; copy number 7: 117; copy number 8: 1; copy number 9: 26; copy number 14: 1; copy number 16: 3.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A3OD-01A-11D-A21P-01): tumor purity 0.42, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–1): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr1:33,838,523–33,840,140, 1 gene: HSPD1P14.
- chr2:202,075,410–202,117,062, 1 gene (within-gene range 0–2): KIAA2012-AS1.
- chr5:145,001,853–145,005,789, 1 gene: NAMPTP2.
- chr6:14,646,535–14,646,638, 1 gene: RNU6-793P.
- chr6:114,822,994–115,002,280, 2 genes (within-gene range 0–2): AL590550.1, RNU6-475P.
- chr9:135,479,079–135,501,734, 2 genes (within-gene range 0–2): PPP1R26, C9orf116.
- chr11:127,657,568–127,657,877, 1 gene: AP003532.1.
- chr14:21,962,819–22,482,959, 41 genes (within-gene range 0–2): AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.
- chr14:42,362,983–42,808,112, 5 genes (within-gene range 0–2): AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1.
- chr18:45,989,653–45,989,945, 1 gene: RN7SKP26.
- chr19:9,087,061–9,126,950, 5 genes: OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3.
- chr21:45,974,489–46,005,050, 2 genes: AJ011932.1, COL6A1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,191 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:210,676,823–248,919,946, 837 genes, copy number 5 (broad region; genes not listed).
- chr2:20,155,618–20,156,057, 1 gene, copy number 14: RPS16P2.
- chr2:88,811,186–88,861,563, 1 gene, copy number 9 (within-gene range 2–9): AC244205.1.
- chr2:88,857,161–89,046,466, 20 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr4:154,754,756–154,781,873, 2 genes, copy number 6: AC009567.1, AC009567.2.
- chr4:154,787,118–154,790,484, 2 genes, copy number 6: RNU2-66P, RNU2-44P.
- chr4:176,308,268–176,320,458, 1 gene, copy number 7 (within-gene range 2–7): SPCS3-AS1.
- chr6:31,479,973–31,511,124, 3 genes, copy number 16: MICB-DT, MICB, Y_RNA.
- chr11:68,903,863–74,842,413, 207 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr11:74,830,574–74,846,209, 2 genes, copy number 5: AP000560.1, RN7SL239P.
- chr11:76,186,325–79,441,030, 71 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:81,821,272–83,423,516, 35 genes, copy number 5: MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr13:31,063,306–31,115,699, 1 gene, copy number 5 (within-gene range 1–9): WDR95P.
- chr15:71,332,120–71,352,460, 2 genes, copy number 6: AC064799.2, AC064799.1.
- chr17:46,035,313–46,035,770, 1 gene, copy number 8: CR936218.1.
- chr19:15,611,623–15,662,825, 5 genes, copy number 9 (within-gene range 4–9): AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3.

Autosomal genes at a single copy (total copy number 1): 10,098. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
